Somatic mutation profile of tumor specimen TCGA-ZX-AA5X-01A (aliquot TCGA-ZX-AA5X-01A-11D-A42O-09) from TCGA case TCGA-ZX-AA5X, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 64.2 years (23,440 days).
Specimen TCGA-ZX-AA5X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90348835-1370-42c4-898c-3f5eaad5abde.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZX-AA5X-10A (Blood Derived Normal), aliquot TCGA-ZX-AA5X-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6111d386-2875-45d4-9918-1acaa63c4820

The open-access MAF lists 71 somatic variants for this specimen: 50 protein-altering or splice-affecting, 19 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 19, Nonsense Mutation 3, Splice Site 1, Frame Shift Ins 1, Intron 1, In Frame Del 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS16 | c.2750C>T p.T917M | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); catalogued as rs192673903; called by muse, mutect2, varscan2
- ADIG | c.29A>G p.N10S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.035); catalogued as COSV99485461; called by muse, mutect2, varscan2
- AGMO | c.418A>G p.I140V | Missense Mutation (SNP) | VAF 10/88 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.123); catalogued as COSV100694411; called by muse, mutect2
- AHCYL1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.706); catalogued as COSV100779289; called by muse, mutect2, varscan2
- CBLB | c.2936G>A p.R979H | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs778405917, COSV51433674; called by muse, mutect2, varscan2
- CD276 | c.274C>T p.R92C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs562558740, COSV59203915; called by muse, mutect2, varscan2
- CFAP61 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 11/55 reads (20%) | catalogued as rs201899206, COSV55647489; called by muse, mutect2, varscan2
- CLK3 | c.1466G>A p.R489H (on ENST00000395066 / NM_001130028.1; = p.R341H on NM_003992.4) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775653210, COSV59340727; called by mutect2, varscan2
- CSNK1G1 | c.1099C>T p.R367* | Nonsense Mutation (SNP) | VAF 13/80 reads (16%) | catalogued as COSV57307612; called by muse, mutect2, varscan2
- EIF5B | c.416A>G p.D139G | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as COSV56816284; called by muse, mutect2, varscan2
- EP300 | c.4306T>A p.W1436R | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54342708, COSV99609154; called by muse, mutect2, varscan2
- FTSJ3 | c.1938_1940del p.D647del | In Frame Del (DEL) | VAF 6/42 reads (14%) | catalogued as rs1567751459; called by pindel, varscan2
- GALK2 | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100509029; called by muse, mutect2, varscan2
- GMIP | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.034); catalogued as COSV99179376; called by muse, mutect2
- GNLY | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV99808986; called by muse, mutect2, varscan2
- GPATCH2L | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs769541023, COSV55052533; called by muse, mutect2, varscan2
- GRIA2 | c.2107T>C p.F703L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99645160; called by muse, mutect2, varscan2
- KRT81 | c.1337G>A p.R446Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.019); catalogued as rs139838048; called by muse, mutect2, varscan2
- LARGE1 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as rs754744384, COSV100505896, COSV61659079; ClinVar: uncertain significance; called by mutect2, varscan2
- LDB2 | c.1034C>T p.A345V | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.225); catalogued as rs1204888185, COSV58771153, COSV58772049; called by muse, mutect2, varscan2
- MBOAT1 | c.946G>A p.G316R | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs199705606, COSV61128200; called by muse, mutect2, varscan2
- MDGA2 | c.2416G>T p.A806S (on ENST00000399232 / NM_001113498.2; = p.A508S on NM_182830.4) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0.381); catalogued as COSV100637543; called by muse, mutect2, varscan2
- MEOX2 | c.40G>A p.A14T | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.161); catalogued as COSV100012020; called by muse, mutect2
- MICAL1 | c.1400C>T p.P467L | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV100668645; called by muse, mutect2
- MMP9 | c.1397C>T p.T466M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as rs1291812181, COSV63434152; called by muse, mutect2, varscan2
- MYH6 | c.35C>T p.A12V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.445); catalogued as rs562487638, COSV100676784; ClinVar: uncertain significance; called by mutect2, varscan2
- NELFB | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs1473329938, COSV100546968; called by muse, mutect2, varscan2
- P3H4 | c.1025G>A p.R342H | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.028); catalogued as rs782752371, COSV100821276; called by muse, mutect2, varscan2
- PIP5K1C | c.271G>A p.V91M | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1399261015, COSV100095700; called by muse, mutect2, varscan2
- RPH3A | c.455G>A p.R152H (on ENST00000389385 / NM_001143854.2; = p.R148H on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757648559, COSV66991409; called by muse, mutect2, varscan2
- SEC24C | c.2266C>T p.R756W | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59539537; called by muse, mutect2, varscan2
- SGF29 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.34); PolyPhen benign (0.411); catalogued as rs71391315, COSV100396962; called by muse, mutect2, varscan2
- SRD5A3 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.994); catalogued as COSV99948104; called by muse, mutect2
- SRPX2 | c.1297G>A p.E433K | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV99343072; called by muse, mutect2, varscan2
- SYNPR | c.356T>C p.I119T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); catalogued as COSV99888697; called by muse, mutect2, varscan2
- TEX15 | c.1939G>A p.E647K (on ENST00000256246; = p.E1030K on NM_001350162.2) | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.319); catalogued as rs1462041378, COSV56343563; called by muse, mutect2, varscan2
- THOC2 | c.597A>C p.L199F | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99833744; called by muse, varscan2
- TMEM200C | c.1642G>A p.E548K | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as COSV101274847; called by muse, mutect2, varscan2
- TMF1 | c.2800C>T p.R934C | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs568158325, COSV68375667; called by muse, mutect2, varscan2
- TOP2B | c.547C>T p.R183C (on ENST00000264331 / NM_001330700.2; = p.R178C on NM_001068.3) | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51973932; called by muse, mutect2, varscan2
- TOPORS | c.620C>T p.P207L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs1331867715, COSV100745189; called by muse, mutect2, varscan2
- TRMT11 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs144488568; called by muse, mutect2, varscan2
- TRPM3 | c.355C>T p.R119* (on ENST00000357533 / NM_001366142.2; = p.R88* on NM_001007471.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 13/73 reads (18%) | catalogued as rs763880806, COSV100625119; called by muse, mutect2, varscan2
- USP21 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV99237605; called by muse, mutect2, varscan2
- ZNF32 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as COSV100986505; called by muse, mutect2, varscan2
- ZNF777 | c.1793T>C p.V598A | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1156534293, COSV56100685, COSV99925255; called by muse, mutect2, varscan2
- ZSWIM8 | c.2605G>A p.A869T | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV101290030; called by muse, mutect2, varscan2
- ZYG11B | c.1695+1G>A p.X565_splice | Splice Site (SNP) | VAF 15/85 reads (18%) | catalogued as COSV99597605; called by muse, mutect2, varscan2
- C5 | c.2582C>T p.A861V | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.005); called by muse, mutect2
- HLA-B | c.696dup p.Y233Lfs*21 | Frame Shift Ins (INS) | VAF 21/66 reads (32%) | called by mutect2, pindel, varscan2
- AGK | c.1077C>T p.H359= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs573580414, COSV100814667; called by muse, mutect2, varscan2
- ATP1B4 | c.897C>T p.Y299= (on ENST00000218008 / NM_001142447.3; = p.Y295= on NM_012069.5) | Silent (SNP) | VAF 4/32 reads (13%) | catalogued as rs148650396, COSV54311543; called by mutect2, varscan2
- BAHCC1 | c.5478C>T p.N1826= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs782249602, COSV57028300; called by muse, mutect2, varscan2
- DNAJB12 | c.852G>A p.L284= (on ENST00000338820; = p.L250= on NM_017626.6 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV58761346; called by muse, mutect2
- FMO5 | c.1345C>T p.L449= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV99567222; called by muse, mutect2, varscan2
- FUT10 | c.891G>A p.L297= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs766273033, COSV100161580; called by muse, mutect2, varscan2
- HTR3E | c.1230G>A p.Q410= (on ENST00000415389 / NM_001256613.1; = p.Q425= on NM_182589.2) | Silent (SNP) | VAF 5/33 reads (15%) | catalogued as COSV100094289, COSV58947058; called by muse, mutect2, varscan2
- IL31RA | c.2294A>G p.*765= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV100732749; called by mutect2, varscan2
- KBTBD2 | c.606A>G p.L202= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV100406536; called by muse, mutect2, varscan2
- OR6B2 | c.297G>A p.T99= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs566028555, COSV99401656; called by muse, mutect2
- PGLYRP2 | c.597C>T p.V199= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV99484164; called by muse, mutect2, varscan2
- PTPN21 | c.459T>A p.G153= | Silent (SNP) | VAF 11/154 reads (7%) | catalogued as COSV100162251; called by muse, mutect2
- ROCK1 | c.3892T>C p.L1298= | Silent (SNP) | VAF 21/116 reads (18%) | catalogued as COSV101296491; called by muse, mutect2, varscan2
- SLC19A2 | c.528G>T p.G176= | Silent (SNP) | VAF 8/54 reads (15%) | catalogued as rs757282335, COSV99357036; called by muse, mutect2, varscan2
- SLC26A11 | c.1251G>A p.P417= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs137973400, COSV63279154; called by muse, mutect2, varscan2
- TNFRSF11A | c.1140G>T p.V380= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV54022187, COSV99500361; called by muse, varscan2
- USE1 | c.57G>A p.A19= | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV99812541; called by mutect2, varscan2
- WDR7 | c.2511C>G p.L837= | Silent (SNP) | VAF 18/90 reads (20%) | catalogued as COSV99589841; called by muse, mutect2, varscan2
- ZNF236 | c.1059G>A p.A353= | Silent (SNP) | VAF 14/67 reads (21%) | catalogued as rs748176355, COSV99470728; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824544 C>T | 5'Flank (SNP) | VAF 22/220 reads (10%) | called by muse, mutect2
- NDEL1 | c.944+3187_944+3189del | Intron (DEL) | VAF 8/68 reads (12%) | called by pindel, varscan2
